Somatic mutation profile of tumor specimen TCGA-3H-AB3K-01A (aliquot TCGA-3H-AB3K-01A-11D-A39R-32) from TCGA case TCGA-3H-AB3K, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 64.6 years (23,591 days).
Specimen TCGA-3H-AB3K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eb2a2e6-0838-4e6f-a890-0453e7efc654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3K-10A (Blood Derived Normal), aliquot TCGA-3H-AB3K-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/027084d9-04b3-4135-81bd-7d6117ade302

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs121434259, CM930513, COSV58519659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAD | c.6475G>A p.E2159K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs763286841; called by muse, mutect2, varscan2
- CRYBG1 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs369540763; called by muse, mutect2, varscan2
- DROSHA | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.011); catalogued as rs758120846, COSV60772850; called by muse, mutect2, varscan2
- NISCH | c.2150A>T p.H717L | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV61901765; called by muse, mutect2, varscan2
- VWA3B | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as rs747469562; called by muse, mutect2, varscan2
- BAP1 | c.139_140del p.I47Lfs*21 | Frame Shift Del (DEL) | VAF 23/43 reads (53%) | called by mutect2, pindel, varscan2
- NSF | c.1773T>G p.D591E | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- OR5F1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF17 | c.16T>A p.S6T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC45A4 | c.703T>G p.F235V (on ENST00000517878 / NM_001286646.2; = p.F184V on NM_001080431.2) | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 72/94 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBTD1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CKAP5 | c.2629A>C p.R877= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, varscan2
- CUBN | c.8151G>T p.S2717= | Silent (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- SRSF4 | c.462A>G p.K154= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- ABCA2 | chr9:137033106 C>T | 5'Flank (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
